TARGET case TARGET-40-NAAHBM — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/90ab0f98-5605-5980-965a-d70d00443a1d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 14 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 14.4 years (5,254 days); Year of diagnosis: 1999; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 1,132 days (3.1 years); Sites of involvement: Lung, NOS.
   Pathology details: Necrosis percent: 20.
   Treatment given: Protocol identifier: BCM.

Follow-up (2 entries)
- Days to follow up: 483 days (1.3 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 483 days (1.3 years); Days to first event: 483 days (1.3 years); First event: Relapse.
- Days to follow up: 1,132 days (3.1 years); Year of follow up: 2002.

Biospecimens (4 samples)
- Sample TARGET-40-NAAHBM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHBM-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHBM-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
- Sample TARGET-40-NAAHBM-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1132
- Protocol: BCM
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Proximal
- Definitive Surgery: Limb sparing
- Site of initial relapse: Lung
- Histologic response: Stage 1/2 (0-90 % necrosis)
